Gene-level copy-number profile of tumor specimen HTMCP-03-06-02092-01A from CGCI case HTMCP-03-06-02092, project CGCI-HTMCP-CC (HIV+ Tumor Molecular Characterization Project - Cervical Cancer). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, nonkeratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIIB; Tumor grade: G2.
Specimen HTMCP-03-06-02092-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file b1d82d1f-d294-4b3b-aa67-48fe2b850b6d.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HTMCP-03-06-02092-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,227 have no estimate.
https://portal.gdc.cancer.gov/files/2ba7fc68-b942-4c60-93bd-388089bff9b2

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 42; copy number 2: 8,094; copy number 3: 25,737; copy number 4: 19,096; copy number 5: 4,591; copy number 6: 137; copy number 7: 679; copy number 8: 9; copy number 11: 1; copy number 16: 4; copy number 17: 2; copy number 29: 4.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 699 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,343,180–143,500,512, 7 genes, copy number 8–17: AC242852.1, AC242852.2, AC239859.5, RNA5SP533, AC239859.3, AC239859.2, LINC02799.
- chr2:89,872,463–89,872,702, 1 gene, copy number 8: IGKV2D-38.
- chr2:89,913,982–89,916,052, 1 gene, copy number 11: IGKV1D-33.
- chr2:90,359,809–90,367,699, 2 genes, copy number 8: AC233263.1, AC233263.7.
- chr5:58,198–45,895,970, 679 genes, copy number 7 (broad region; genes not listed).
- chr6:29,934,101–29,934,286, 1 gene, copy number 8: HLA-U.
- chr15:90,529,923–90,717,141, 8 genes, copy number 16–29: CRTC3, AC103739.1, AC103739.2, CRTC3-AS1, AC103739.3, HSPE1P3, AC021422.1, LINC01585.

Autosomal genes at a single copy (total copy number 1): 42. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
